CCDI case PBBMBU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2aa21f6d-e546-494d-b3c0-5fa41c39e352

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,592 days).

Biospecimens (3 samples)
- Sample 0DC7SQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DC7ST: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DC7T4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
